FM case AD13737 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Transitional Cell Papillomas and Carcinomas; Primary site: Ureter.
https://portal.gdc.cancer.gov/cases/274613ee-83bb-4ce5-b3b4-f4e9714de090

Female, 63.5 years: Urothelial carcinoma, NOS (ICD-O-3 8120/3) of the ureter; metastasis biopsied or resected from the kidney. Tumor nuclei on the sequenced sample's slide: 43% (pathologist estimate recorded by GDC). Sample type: Metastatic.
